Somatic mutation profile of tumor specimen MP2PRT-PAULSM-TMP1-A (aliquot MP2PRT-PAULSM-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAULSM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (881 days).
Specimen MP2PRT-PAULSM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddf7b28e-117b-40d7-b136-dc323bc57a8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULSM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULSM-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5452107-f839-4d8c-9bd5-21aa68996ba9

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 64/403 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KDM5A | c.2216A>G p.Y739C | Missense Mutation (SNP) | VAF 58/331 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1353488170; called by muse, mutect2, varscan2
- NID1 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 87/512 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776225011; called by muse, mutect2, varscan2
- POU5F1B | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 34/844 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs773140691, COSV101196980; called by muse, mutect2
- DOCK11 | c.1190T>A p.F397Y | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.047); called by muse, mutect2
- SLC13A1 | c.420C>A p.N140K | Missense Mutation (SNP) | VAF 44/343 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORL1 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SYDE2 | c.3028G>A p.A1010T | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2
- CHADL | c.477G>A p.A159= | Silent (SNP) | VAF 26/646 reads (4%) | catalogued as rs1471282563; called by muse, mutect2
- MCF2L | c.170-45367G>A | Intron (SNP) | VAF 50/253 reads (20%) | catalogued as COSV65077732, COSV65083400; called by muse, mutect2, varscan2
